Gene-level copy-number profile of tumor specimen BLGSP-71-21-00243-01A from CGCI case BLGSP-71-21-00243, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 63.7 years (23,274 days).
Specimen BLGSP-71-21-00243-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c47e230b-b778-4eb2-a9ba-f05c615b08a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-21-00243-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/16b90d26-6f44-40ec-a20f-9f8c2bd2d910

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,396; copy number 2: 54,318; copy number 3: 1,157; copy number 4: 1; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,839,483–148,839,732, 1 gene (within-gene range 0–2): RN7SKP88.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:75,391,955–75,410,996, 2 genes, copy number 7 (within-gene range 3–7): AC211486.1, TRIM73.

Autosomal genes at a single copy (total copy number 1): 547. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
